Somatic mutation profile of cancer-model specimen HCM-BROD-0481-C43-85M (Adherent Cell Line, passage 11; aliquot HCM-BROD-0481-C43-85M-01D-A79C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0481-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 63.5 years (23,182 days).
Specimen HCM-BROD-0481-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8eb7346a-949e-4b16-8eda-0fd3da08be7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0481-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0481-C43-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/284284b9-a846-4c1b-826d-d043c21fc292

The open-access MAF lists 150 somatic variants for this specimen: 118 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 29, Nonsense Mutation 10, Splice Region 5, Frame Shift Del 5, Intron 2, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRA2 | c.339G>A p.L113= | Splice Region (SNP) | VAF 30/472 reads (6%) | catalogued as rs1449093152; called by muse, mutect2
- CD3D | c.127T>G p.W43G | Missense Mutation (SNP) | VAF 39/528 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV52674117; called by muse, mutect2
- CPXCR1 | c.143C>A p.P48Q | Missense Mutation (SNP) | VAF 104/417 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV52164425; called by muse, mutect2, varscan2
- DKK2 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 35/488 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.076); catalogued as rs1359603661; called by muse, mutect2
- FIGNL2 | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 24/392 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs753823722; called by muse, mutect2
- GFAP | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 40/806 reads (5%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.999); catalogued as rs1401647655; called by muse, mutect2
- GRPEL1 | c.234_235del p.Y78* | Nonsense Mutation (DEL) | VAF 28/99 reads (28%) | catalogued as rs1276745944; called by pindel, varscan2
- HELZ2 | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 45/1100 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV64409055; called by muse, mutect2
- HSD17B1 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 164/559 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs763124847; called by muse, mutect2, varscan2
- HTR7 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 156/482 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs759637515, COSV99520254; called by muse, mutect2, varscan2
- KBTBD7 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 88/284 reads (31%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs758529155; called by muse, mutect2, varscan2
- KCNH2 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 28/792 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as COSV51222170; called by muse, mutect2
- KRT2 | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 90/301 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1330514030; called by muse, mutect2, varscan2
- MAGEC1 | c.1671C>A p.D557E | Missense Mutation (SNP) | VAF 390/812 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV53569738; called by mutect2, varscan2
- NPC1L1 | c.611A>G p.N204S | Missense Mutation (SNP) | VAF 819/1273 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs1348671323; called by muse, mutect2, varscan2
- PCDHB14 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 266/800 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.251); catalogued as rs777821767, COSV53386829, COSV99505975; called by muse, mutect2
- POM121L2 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 124/380 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV66277045; called by muse, mutect2, varscan2
- RNASE6 | c.410C>A p.P137H | Missense Mutation (SNP) | VAF 18/502 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100485908; called by muse, mutect2
- SCN11A | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 117/369 reads (32%) | catalogued as rs1390064103, COSV56579675; called by muse, mutect2, varscan2
- SEC31A | c.2651C>T p.P884L (on ENST00000355196 / NM_001318120.1; = p.P845L on NM_016211.4) | Missense Mutation (SNP) | VAF 99/201 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs889981605, COSV100021528; called by muse, mutect2, varscan2
- SH2B2 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 265/1782 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.103); catalogued as rs1554553581, COSV60827055; called by muse, mutect2, varscan2
- SLC52A3 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 72/1185 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs779187229; called by muse, mutect2
- SLC6A17 | c.1952T>C p.L651P | Missense Mutation (SNP) | VAF 13/408 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1262706847; called by muse, mutect2
- SLC8B1 | c.1569C>G p.D523E | Missense Mutation (SNP) | VAF 134/319 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.037); catalogued as rs748511708; called by muse, mutect2, varscan2
- STON1 | c.1873G>T p.E625* | Nonsense Mutation (SNP) | VAF 273/354 reads (77%) | catalogued as rs1397451696; called by muse, mutect2, varscan2
- SYNE1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs560155321, COSV54928364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAP1 | c.1933G>A p.G645R | Missense Mutation (SNP) | VAF 117/434 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs1024069465; called by muse, mutect2, varscan2
- TDRD5 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 18/458 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99676788; called by muse, mutect2
- TENM1 | c.1270A>G p.I424V | Missense Mutation (SNP) | VAF 130/363 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs751228319; called by muse, mutect2, varscan2
- TMEM44 | c.1217C>A p.S406Y (on ENST00000392432 / NM_001166305.2; = p.S359Y on NM_138399.5) | Missense Mutation (SNP) | VAF 68/788 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.361); catalogued as COSV56451497; called by muse, mutect2
- TONSL | c.1217C>G p.A406G | Missense Mutation (SNP) | VAF 30/598 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.251); catalogued as COSV101340178; called by muse, mutect2
- TRIM31 | c.508T>C p.F170L | Missense Mutation (SNP) | VAF 22/530 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs199773605; called by muse, mutect2
- TRIO | c.8141C>T p.A2714V | Missense Mutation (SNP) | VAF 149/849 reads (18%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.977); catalogued as rs867105587; called by muse, varscan2
- TRPV1 | c.1688G>A p.G563D | Missense Mutation (SNP) | VAF 94/318 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs575489206; called by muse, mutect2, varscan2
- TTN | c.11689C>T p.P3897S (on ENST00000591111; = p.P3851S on NM_003319.4) | Missense Mutation (SNP) | VAF 136/230 reads (59%) | catalogued as COSV59953079; called by muse, mutect2, varscan2
- UBE2J1 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 86/288 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs776129230, COSV70561477; called by muse, mutect2, varscan2
- UBE2U | c.132G>T p.Q44H | Missense Mutation (SNP) | VAF 54/86 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV64280422, COSV64281451; called by muse, mutect2, varscan2
- UNC13C | c.6175G>A p.G2059R | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52859208; called by muse, mutect2
- WARS1 | c.1165C>A p.Q389K | Missense Mutation (SNP) | VAF 171/522 reads (33%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV100690244; called by muse, mutect2, varscan2
- ZNF727 | c.407G>A p.C136Y | Missense Mutation (SNP) | VAF 134/474 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV101407030; called by muse, mutect2, varscan2
- ABCA9 | c.4483del p.V1495Cfs*5 | Frame Shift Del (DEL) | VAF 121/405 reads (30%) | called by mutect2, pindel, varscan2
- ACE | c.2749C>A p.P917T | Missense Mutation (SNP) | VAF 19/330 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2
- AFMID | c.780+5T>A | Splice Region (SNP) | VAF 32/490 reads (7%) | called by muse, mutect2
- AIFM1 | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 32/716 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.196); called by muse, mutect2
- ALDH1L1 | c.2308G>A p.A770T | Missense Mutation (SNP) | VAF 201/591 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANK3 | c.11750A>C p.N3917T | Missense Mutation (SNP) | VAF 130/450 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- APLF | c.1158T>C p.Y386= | Splice Region (SNP) | VAF 39/134 reads (29%) | called by muse, mutect2, varscan2
- BZW1 | c.634G>C p.D212H | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CACHD1 | c.3113A>C p.D1038A | Missense Mutation (SNP) | VAF 115/244 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CCDC114 | c.1473G>A p.V491= | Splice Region (SNP) | VAF 36/430 reads (8%) | called by muse, mutect2
- CD3D | c.128G>T p.W43L | Missense Mutation (SNP) | VAF 39/530 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- CHD1 | c.54C>A p.S18R | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.693); called by muse, mutect2
- CLIP2 | c.551T>C p.V184A | Missense Mutation (SNP) | VAF 38/1576 reads (2%) | SIFT tolerated (0.87); PolyPhen benign (0.251); called by muse, mutect2
- CRAMP1 | c.3433T>G p.S1145A | Missense Mutation (SNP) | VAF 209/467 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- DNAH11 | c.1679T>A p.F560Y | Missense Mutation (SNP) | VAF 43/309 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH9 | c.3934G>A p.V1312M | Missense Mutation (SNP) | VAF 46/606 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- DPH2 | c.919A>C p.T307P | Missense Mutation (SNP) | VAF 37/592 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.305); called by muse, mutect2
- EMP1 | c.324C>A p.C108* | Nonsense Mutation (SNP) | VAF 17/204 reads (8%) | called by muse, mutect2
- EPG5 | c.3469C>A p.H1157N | Missense Mutation (SNP) | VAF 30/546 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FBXW10 | c.2503T>A p.C835S | Missense Mutation (SNP) | VAF 24/483 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, mutect2
- GDPD3 | c.845A>T p.E282V | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- HELZ2 | c.6231G>T p.K2077N (on ENST00000467148 / NM_001037335.2; = p.K1508N on NM_033405.3) | Missense Mutation (SNP) | VAF 60/976 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.011); called by muse, mutect2
- HSD17B6 | c.704A>T p.K235M | Missense Mutation (SNP) | VAF 19/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- HTR6 | c.540C>A p.C180* | Nonsense Mutation (SNP) | VAF 38/761 reads (5%) | called by muse, mutect2
- ITGA10 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 14/499 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ITGAM | c.2405A>T p.N802I (on ENST00000648685 / NM_001145808.2; = p.N801I on NM_000632.4) | Missense Mutation (SNP) | VAF 14/414 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.07); called by muse, mutect2
- ITIH3 | c.588G>T p.M196I | Missense Mutation (SNP) | VAF 37/520 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.028); called by muse, mutect2
- IVL | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 150/985 reads (15%) | called by muse, varscan2
- KMT2E | c.257A>G p.K86R | Missense Mutation (SNP) | VAF 235/697 reads (34%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- KPRP | c.1497C>A p.S499R | Missense Mutation (SNP) | VAF 44/616 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.06); called by muse, mutect2
- KRTAP4-6 | c.474C>G p.S158R | Missense Mutation (SNP) | VAF 352/2566 reads (14%) | SIFT tolerated (0.1); called by muse, mutect2
- LAIR2 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 45/342 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- LAMA4 | c.1571G>A p.R524K (on ENST00000230538 / NM_001105206.3; = p.R517K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- LIM2 | c.77A>G p.D26G | Missense Mutation (SNP) | VAF 39/523 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- LLGL1 | c.2233G>C p.A745P | Missense Mutation (SNP) | VAF 210/592 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LNX1 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 14/389 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LOXHD1 | c.4068G>T p.R1356S | Missense Mutation (SNP) | VAF 115/415 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYH15 | c.5384G>A p.R1795K | Missense Mutation (SNP) | VAF 36/453 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2
- NECTIN3 | c.1476A>T p.K492N | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLGN3 | c.1103C>A p.A368D (on ENST00000358741 / NM_181303.2; = p.A348D on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 179/760 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- NRAP | c.4244A>G p.D1415G (on ENST00000359988 / NM_001322945.2; = p.D1380G on NM_006175.4) | Missense Mutation (SNP) | VAF 133/410 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUP98 | c.3441G>A p.W1147* (on ENST00000359171 / NM_001365126.1; = p.W1130* on NM_016320.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 32/676 reads (5%) | called by muse, mutect2
- OOSP2 | c.345T>A p.S115= | Splice Region (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- OVOL1 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 32/567 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.336); called by muse, mutect2
- PARD3 | c.2977G>T p.D993Y | Missense Mutation (SNP) | VAF 86/275 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- PKDREJ | c.1557T>G p.Y519* | Nonsense Mutation (SNP) | VAF 18/246 reads (7%) | called by muse, mutect2
- PRKCSH | c.1432T>G p.S478A | Missense Mutation (SNP) | VAF 126/432 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.34); called by mutect2, varscan2
- PRR32 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 138/627 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PTEN | c.672_684del p.Y225Qfs*27 | Frame Shift Del (DEL) | VAF 63/268 reads (24%) | called by mutect2, pindel, varscan2
- RBM12 | c.109G>T p.G37W | Missense Mutation (SNP) | VAF 20/538 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RETREG2 | c.764A>C p.H255P | Missense Mutation (SNP) | VAF 127/407 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- RORA | c.1369C>G p.L457V (on ENST00000335670 / NM_134261.3; = p.L482V on NM_002943.3) | Missense Mutation (SNP) | VAF 22/275 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); called by muse, mutect2
- SEZ6 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 350/539 reads (65%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLC25A27 | c.943A>G p.R315G | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMTN | c.2266C>A p.P756T | Missense Mutation (SNP) | VAF 44/701 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SOX12 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 299/2058 reads (15%) | called by muse, mutect2, varscan2
- SPEN | c.4216T>G p.F1406V | Missense Mutation (SNP) | VAF 103/213 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- SPRED1 | c.247_248insT p.N83Ifs*2 | Frame Shift Ins (INS) | VAF 77/128 reads (60%) | called by pindel, varscan2
- SSRP1 | c.915C>G p.N305K | Missense Mutation (SNP) | VAF 300/454 reads (66%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ST18 | c.1513G>T p.A505S | Missense Mutation (SNP) | VAF 119/238 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- STAT4 | c.2224A>C p.K742Q | Missense Mutation (SNP) | VAF 75/125 reads (60%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBX20 | c.305G>T p.C102F | Missense Mutation (SNP) | VAF 65/1432 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- TBXT | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 204/637 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- TFIP11 | c.746del p.K249Rfs*21 | Frame Shift Del (DEL) | VAF 144/499 reads (29%) | called by mutect2, pindel, varscan2
- TFRC | c.1831T>C p.Y611H | Missense Mutation (SNP) | VAF 128/378 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TMEM135 | c.674_679delinsGC p.L225Rfs*42 | Frame Shift Del (DEL) | VAF 37/132 reads (28%) | called by pindel, varscan2*
- TPM3 | c.473A>G p.E158G | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.52); called by muse, mutect2
- TXK | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 88/195 reads (45%) | called by muse, mutect2, varscan2
- TXK | c.321A>T p.E107D | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- VEGFD | c.934T>C p.C312R | Missense Mutation (SNP) | VAF 51/301 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VPS13C | c.3465C>G p.F1155L (on ENST00000644861 / NM_020821.3; = p.F1112L on NM_017684.5) | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- VWA3A | c.3470C>G p.A1157G | Missense Mutation (SNP) | VAF 23/381 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2
- VWA5B2 | c.860T>A p.L287Q | Missense Mutation (SNP) | VAF 43/630 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); called by muse, mutect2
- WWC2 | c.1631C>A p.A544D | Missense Mutation (SNP) | VAF 149/368 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZBTB7C | c.1486G>C p.G496R | Missense Mutation (SNP) | VAF 45/1126 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.018); called by muse, mutect2
- ZKSCAN1 | c.407T>C p.L136P | Missense Mutation (SNP) | VAF 114/406 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, varscan2
- ZKSCAN1 | c.413_420del p.L138Sfs*11 | Frame Shift Del (DEL) | VAF 92/360 reads (26%) | called by pindel, varscan2
- ZNF282 | c.1910A>G p.K637R | Missense Mutation (SNP) | VAF 232/1379 reads (17%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- AL117339.4 | c.351G>A p.G117= | Silent (SNP) | VAF 79/264 reads (30%) | called by muse, mutect2, varscan2
- C1S | c.1863A>T p.G621= | Silent (SNP) | VAF 43/347 reads (12%) | called by muse, mutect2, varscan2
- CNTN6 | c.2496T>A p.T832= | Silent (SNP) | VAF 52/178 reads (29%) | catalogued as rs766324810; called by muse, mutect2, varscan2
- CPXCR1 | c.144A>C p.P48= | Silent (SNP) | VAF 104/413 reads (25%) | called by muse, mutect2, varscan2
- FBXO46 | c.657C>T p.S219= | Silent (SNP) | VAF 258/589 reads (44%) | catalogued as rs756006396, COSV100480265; called by muse, mutect2, varscan2
- FREM3 | c.1833G>A p.G611= | Silent (SNP) | VAF 38/332 reads (11%) | called by muse, mutect2, varscan2
- FUT2 | c.273G>A p.R91= | Silent (SNP) | VAF 185/454 reads (41%) | called by muse, mutect2, varscan2
- GOLGA4 | c.2400G>A p.L800= | Silent (SNP) | VAF 26/289 reads (9%) | called by muse, mutect2
- HAPLN2 | c.543C>G p.S181= | Silent (SNP) | VAF 161/545 reads (30%) | called by muse, mutect2, varscan2
- KCNG4 | c.192C>T p.N64= | Silent (SNP) | VAF 217/432 reads (50%) | called by muse, mutect2, varscan2
- MAGEC1 | c.1356C>T p.S452= | Silent (SNP) | VAF 30/490 reads (6%) | catalogued as rs141810522; called by muse, mutect2
- NT5DC1 | c.36G>A p.V12= | Silent (SNP) | VAF 364/606 reads (60%) | called by muse, mutect2, varscan2
- NYAP2 | c.543C>G p.P181= | Silent (SNP) | VAF 80/269 reads (30%) | catalogued as COSV56003013; called by muse, mutect2, varscan2
- PCDH8 | c.948T>C p.R316= | Silent (SNP) | VAF 42/1108 reads (4%) | called by muse, mutect2
- PCDHA1 | c.1101C>T p.T367= | Silent (SNP) | VAF 136/370 reads (37%) | catalogued as COSV65377358; called by muse, mutect2, varscan2
- POP1 | c.2643G>A p.E881= | Silent (SNP) | VAF 26/462 reads (6%) | called by muse, mutect2
- RASGRP3 | c.936C>G p.V312= | Silent (SNP) | VAF 28/765 reads (4%) | catalogued as rs1328480709; called by muse, mutect2
- SAMD9 | c.627G>A p.E209= | Silent (SNP) | VAF 63/512 reads (12%) | called by muse, mutect2, varscan2
- SMARCC2 | c.2668C>T p.L890= | Silent (SNP) | VAF 145/364 reads (40%) | catalogued as COSV57216825; called by muse, mutect2, varscan2
- SPOCK2 | c.1137C>T p.I379= | Silent (SNP) | VAF 128/484 reads (26%) | catalogued as rs372959015; called by muse, mutect2, varscan2
- SSTR4 | c.42G>T p.G14= | Silent (SNP) | VAF 75/1337 reads (6%) | called by muse, mutect2
- SVEP1 | c.6177T>C p.L2059= | Silent (SNP) | VAF 260/530 reads (49%) | called by muse, mutect2, varscan2
- TECPR2 | c.3633C>T p.S1211= | Silent (SNP) | VAF 15/436 reads (3%) | called by muse, mutect2
- UBE3D | c.825G>A p.Q275= | Silent (SNP) | VAF 16/304 reads (5%) | called by muse, mutect2
- USP38 | c.441G>C p.L147= | Silent (SNP) | VAF 42/342 reads (12%) | called by muse, mutect2, varscan2
- VEGFD | c.933C>A p.T311= | Silent (SNP) | VAF 54/305 reads (18%) | called by muse, mutect2, varscan2
- VPS16 | c.2074C>T p.L692= | Silent (SNP) | VAF 147/1058 reads (14%) | called by muse, mutect2
- WNK4 | c.1941T>C p.A647= | Silent (SNP) | VAF 16/542 reads (3%) | called by muse, mutect2
- ZFHX4 | c.10014A>G p.Q3338= | Silent (SNP) | VAF 10/268 reads (4%) | called by muse, mutect2
- AOAH | c.1600-1133A>G | Intron (SNP) | VAF 97/681 reads (14%) | called by muse, mutect2, varscan2
- LCORL | chr4:17877519 G>T | 3'Flank (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2
- MCF2L | c.170-12802G>A | Intron (SNP) | VAF 68/998 reads (7%) | called by muse, mutect2
